Surgical pathology report (de-identified scan), TCGA case TCGA-B9-5156, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site UNC, specimen TCGA-B9-5156-01A (Primary Tumor).

[page 1 of 2]
Surgical Pathology Report

Diagnosis:

Left kidney, partial laparoscopic nephrectomy

Histologic tumor type/subtype: renal cell carcinoma, papillary subtype

Histologic grade (if applicable): Fuhrman grade 3 of 4

Tumor size (greatest dimension): 1.7 cm

Extent of tumor invasion:

Capsular invasion/perirenal adipose tissue: Tumor invades into renal capsule; perirenal fat negative for carcinoma.

Gerota's fascia: negative for carcinoma

Renal vein: not applicable

Ureter: not applicable

Venous (large vessel): not identified

Lymphatic (small vessel): not identified

Histologic assessment of surgical margins:

Perirenal adipose tissue: negative for malignancy

Gerota's fascia: negative for malignancy

Adrenal gland: not present

Lymph nodes: none identified

Other significant findings: - Tumor is 0.5 cm from the surgical margin.

- Mild glomerulosclerosis and arteriosclerosis.

- Benign simple cyst.

AJCC Staging:

pT1a

pNx

This staging information is based on information available at the time of this report, and is subject to change pending clinical review and additional information.

Clinical History:

The patient is with a clinical diagnosis of a left renal mass. As, radiology showed an enhancing left renal mass, suspicious for renal cell carcinoma.

Gross Description:

Specimen fixation: Formalin

Type of specimen: Partial, laparoscopic

Side of specimen: Left

Size and weight of specimen: 17.3 grams; 3.6 x 3.5 x 2.9 cm

Orientation: The capsule has been previously inked black and the parenchymal margin of resection has been inked

[page 2 of 2]
blue.

Presence/absence of adrenal gland: Absent

Tumor description/site: The tumor is located in the cortex of the kidney and directly abuts the capsule; the lesion appears encapsulated and is yellow/brown in color with no cysts identified.

Tumor size: 1.7 x 1.5 x 1.4 cm.

Presence/absence of multicentricity: Absent (cannot assess without complete nephrectomy)

Confinement/non-confinement to the kidney: Confined

Extent of invasion:

Perirenal adipose tissue: Tumor does not grossly involve

Gerota's fascia: Does not grossly involve

Renal vein: Not present

Ureter: Not present

Other organs: Not applicable

Surgical margins:

Perirenal adipose tissue: Negative, directly adjacent

Renal vein: Not present

Renal artery: Not present

Ureter: Not present

Description of kidney away from tumor: Tan/brown tissue with the average cortex measuring 4.6 cm in average medullary area measuring 1.0 cm.

Lymph nodes (hilar): Not present

Other significant findings: The tumor is located 0.5 cm away from the blue inked parenchymal margin of resection.

Tissue submitted for special investigations: Yes

Digital photograph taken: No

Block Summary:

Inking: Capsule/black, parenchymal margin of resection/blue

A1 - Perinephric fat margin

A2 - Tumor with closest approach margin of resection

A3-A7 - Additional sections of tumor

A8 - Normal kidney

Light Microscopy:

Light microscopic examination is performed

[REDACTED]

Source: NCI Genomic Data Commons file ad42cbc0-5754-4870-9c08-662799295145 (TCGA-B9-5156.80F7687A-5C28-4624-91C2-9647FCF30C2F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).